Somatic mutation profile of tumor specimen C3L-01031-01 (aliquot CPT0127270006) from CPTAC case C3L-01031, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 65.1 years (23,784 days).
Specimen C3L-01031-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c448b8d1-6bb4-4522-89a9-b59207fc5c93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01031-31 (Blood Derived Normal), aliquot CPT0128520002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f30bdab5-90ea-4fbe-acb3-73abc4aa0bbf

The open-access MAF lists 89 somatic variants for this specimen: 63 protein-altering or splice-affecting, 16 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 16, Intron 4, Splice Site 2, RNA 2, Nonsense Mutation 2, Frame Shift Ins 1, 3'Flank 1, 5'Flank 1, 3'UTR 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 165/525 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 145/429 reads (34%) | hotspot (GDC flag); catalogued as rs868137297, CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ANGPTL4 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 154/717 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs533599788, COSV100035119, COSV100035194, COSV56845072; called by muse, mutect2, varscan2
- C10orf71 | c.4027G>A p.V1343M | Missense Mutation (SNP) | VAF 24/382 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); catalogued as rs906410500, COSV60510676; called by muse, mutect2
- COL6A1 | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 41/440 reads (9%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.723); catalogued as rs369365801, COSV62613550; called by muse, mutect2
- CTNND2 | c.1745A>G p.N582S | Missense Mutation (SNP) | VAF 106/402 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs1422181938; called by muse, mutect2, varscan2
- EMX2 | c.176C>G p.A59G | Missense Mutation (SNP) | VAF 42/598 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV71294466; called by muse, mutect2
- GREB1L | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 72/545 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1266822957; called by muse, mutect2, varscan2
- GSE1 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 31/613 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs199961563, COSV53670208; called by muse, mutect2
- H2BC8 | c.210C>G p.I70M | Missense Mutation (SNP) | VAF 96/290 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as COSV55127461, COSV99773400; called by muse, mutect2, varscan2
- IGSF1 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.18); catalogued as rs778830663, CD1211168, COSV100812485; called by muse, mutect2
- KLK6 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 28/524 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59565217; called by muse, mutect2
- MACF1 | c.18370G>C p.D6124H (on ENST00000372915; = p.D4169H on NM_012090.5) | Missense Mutation (SNP) | VAF 21/508 reads (4%) | catalogued as COSV99240708; called by muse, mutect2
- MTHFD2 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 8/215 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV51201018; called by muse, mutect2
- MUC16 | c.28520C>T p.T9507M | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); catalogued as rs370765065; called by muse, mutect2
- NR0B1 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 21/314 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.403); catalogued as rs1361546449; called by muse, mutect2
- OCA2 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 70/810 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs776631782, COSV62343363; called by muse, mutect2
- OR2M7 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 25/624 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs899067573, COSV58738712; called by muse, mutect2
- PIGO | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 46/551 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs775041042, COSV53055142; ClinVar: uncertain significance; called by muse, mutect2
- PLS1 | c.1766C>T p.S589L | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61833764; called by muse, mutect2, varscan2
- RPEL1 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 61/992 reads (6%) | catalogued as rs753313707, COSV71503334; called by muse, mutect2
- RPH3A | c.1585G>A p.G529R (on ENST00000389385 / NM_001143854.2; = p.G525R on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/382 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs756037748, COSV66990225; called by muse, mutect2, varscan2
- RRP12 | c.3631C>T p.Q1211* | Nonsense Mutation (SNP) | VAF 15/274 reads (5%) | catalogued as COSV100212840; called by muse, mutect2
- RTL8B | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV66954595; called by muse, mutect2
- RUNX1T1 | c.179C>G p.P60R (on ENST00000265814 / NM_001198628.1; = p.P33R on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/317 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs1195054840, COSV56152620, COSV56158222, COSV99752651; called by muse, mutect2
- SLC12A1 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 26/382 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs369307402, COSV101118323; called by muse, mutect2
- SLC39A10 | c.183dup p.Y62Ifs*4 | Frame Shift Ins (INS) | VAF 52/206 reads (25%) | catalogued as rs771462597; called by mutect2, varscan2
- SPPL2A | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550930877, COSV55942276; called by muse, mutect2
- STARD9 | c.6649G>C p.E2217Q | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.522); catalogued as COSV51898800; called by muse, mutect2
- TAF1L | c.1873C>A p.H625N | Missense Mutation (SNP) | VAF 32/386 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54258529; called by muse, mutect2
- TBC1D9 | c.3316G>A p.V1106M | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as rs545624117, COSV71308588; called by muse, mutect2, varscan2
- TDRD6 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs139956934, COSV60176261; called by muse, mutect2
- TDRD7 | c.3238G>A p.D1080N | Missense Mutation (SNP) | VAF 30/574 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs879227282; called by muse, mutect2
- WASHC4 | c.3427G>C p.E1143Q | Missense Mutation (SNP) | VAF 28/428 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1264820654; called by muse, mutect2
- ZFHX4 | c.9703G>A p.E3235K | Missense Mutation (SNP) | VAF 24/437 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs1403930759, COSV99261375; called by muse, mutect2
- ZNF559 | c.674C>G p.S225C | Missense Mutation (SNP) | VAF 11/195 reads (6%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.984); catalogued as rs1389803310; called by muse, mutect2
- ACSBG2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 57/293 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAD2 | c.1550G>C p.R517P (on ENST00000315906 / NM_001145400.2; = p.R599P on NM_139174.4) | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP4B1 | c.1241A>T p.Q414L | Missense Mutation (SNP) | VAF 147/594 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ATP2B3 | c.362C>G p.S121C | Missense Mutation (SNP) | VAF 34/558 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- B3GALT1 | c.960C>A p.S320R | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- CAD | c.6397G>C p.E2133Q | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2
- CMYA5 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 29/480 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.335); called by muse, mutect2
- COL4A1 | c.3054G>T p.L1018F | Missense Mutation (SNP) | VAF 230/972 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CYP46A1 | c.616G>T p.G206C | Missense Mutation (SNP) | VAF 108/273 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- FSIP2 | c.6653G>A p.R2218K | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL27RA | c.810C>G p.F270L | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2
- KCNC2 | c.190C>G p.P64A | Missense Mutation (SNP) | VAF 15/385 reads (4%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.01); called by muse, mutect2
- KIAA1549L | c.394A>T p.I132L (on ENST00000321505; = p.I429L on NM_012194.3) | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- MID1 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 50/834 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.044); called by muse, mutect2
- MPHOSPH10 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MRPL46 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MSH4 | c.491G>A p.R164K | Missense Mutation (SNP) | VAF 19/341 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- MUC5B | c.6443A>G p.N2148S | Missense Mutation (SNP) | VAF 173/1239 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCBP1 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.579); called by muse, mutect2
- NENF | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 28/406 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2
- OR2L2 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.155); called by muse, mutect2
- PNKP | c.1316G>C p.R439P | Missense Mutation (SNP) | VAF 16/380 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.362); called by muse, mutect2
- POM121 | c.2924C>G p.A975G (on ENST00000434423; = p.A710G on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/247 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- SLC7A5 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 34/778 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.042); called by muse, mutect2
- TJAP1 | c.1324C>A p.L442M (on ENST00000372445 / NM_001146016.1; = p.L432M on NM_080604.3) | Missense Mutation (SNP) | VAF 59/468 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- USP24 | c.1342+1G>C p.X448_splice | Splice Site (SNP) | VAF 45/228 reads (20%) | called by muse, mutect2, varscan2
- ZIK1 | c.869C>T p.T290I | Missense Mutation (SNP) | VAF 24/469 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- AFF2 | c.732C>T p.F244= | Silent (SNP) | VAF 25/358 reads (7%) | catalogued as rs370542676, COSV60671578; called by muse, mutect2
- ANKRD11 | c.7287C>T p.P2429= | Silent (SNP) | VAF 234/814 reads (29%) | catalogued as rs751753158; called by muse, mutect2, varscan2
- COL5A2 | c.3912C>T p.S1304= | Silent (SNP) | VAF 112/738 reads (15%) | catalogued as rs571598585; called by muse, mutect2, varscan2
- DLG4 | c.1821C>T p.H607= (on ENST00000399506 / NM_001321075.3; = p.H650= on NM_001365.4) | Silent (SNP) | VAF 14/329 reads (4%) | catalogued as rs1006147091; called by muse, mutect2
- EEF1A2 | c.309C>A p.I103= | Silent (SNP) | VAF 76/343 reads (22%) | called by muse, mutect2, varscan2
- KCNA1 | c.873C>T p.L291= | Silent (SNP) | VAF 18/466 reads (4%) | called by muse, mutect2
- LONRF3 | c.39C>A p.P13= | Silent (SNP) | VAF 25/362 reads (7%) | called by muse, mutect2
- MID1 | c.321C>T p.D107= | Silent (SNP) | VAF 45/199 reads (23%) | catalogued as rs754833237, COSV100452340; called by muse, mutect2, varscan2
- MUC4 | c.14433G>A p.S4811= (on ENST00000463781 / NM_018406.7; = p.S575= on NM_004532.6) | Silent (SNP) | VAF 24/556 reads (4%) | called by muse, mutect2
- NNT | c.1449C>G p.L483= | Silent (SNP) | VAF 9/195 reads (5%) | catalogued as COSV52924967; called by muse, mutect2
- NRG2 | c.2403G>A p.A801= | Silent (SNP) | VAF 216/760 reads (28%) | called by muse, mutect2, varscan2
- SLC6A3 | c.1422C>G p.L474= | Silent (SNP) | VAF 49/1263 reads (4%) | called by muse, mutect2
- SRRM2 | c.4539G>A p.Q1513= | Silent (SNP) | VAF 29/626 reads (5%) | called by muse, mutect2
- TAF4B | c.276G>A p.Q92= | Silent (SNP) | VAF 44/697 reads (6%) | catalogued as rs780195768; called by muse, mutect2
- TMEM72 | c.702C>T p.S234= | Silent (SNP) | VAF 46/299 reads (15%) | catalogued as COSV101273622; called by muse, mutect2, varscan2
- TRAPPC9 | c.2133A>G p.Q711= | Silent (SNP) | VAF 26/390 reads (7%) | catalogued as rs1314800707; called by muse, mutect2
- CARMIL3 | chr14:24049306 G>A | 5'Flank (SNP) | VAF 32/472 reads (7%) | called by muse, mutect2
- DNAJB6 | c.346+1924T>G | Intron (SNP) | VAF 103/469 reads (22%) | called by muse, mutect2, varscan2
- GABRA1 | c.1060-28C>A | Intron (SNP) | VAF 62/251 reads (25%) | called by muse, mutect2, varscan2
- LINC02740 | n.166G>T | RNA (SNP) | VAF 55/355 reads (15%) | called by muse, mutect2, varscan2
- MIDEAS | c.*337A>G | 3'UTR (SNP) | VAF 34/106 reads (32%) | called by muse, mutect2, varscan2
- NBPF7 | n.643G>C | RNA (SNP) | VAF 155/593 reads (26%) | called by muse, mutect2, varscan2
- TPM1 | c.240+4423G>A | Intron (SNP) | VAF 12/219 reads (5%) | catalogued as COSV99147790; called by muse, mutect2
- TRADD | c.429+17G>T | Intron (SNP) | VAF 144/1002 reads (14%) | called by muse, mutect2, varscan2
- Y_RNA | chr7:23490630 C>T | 3'Flank (SNP) | VAF 23/422 reads (5%) | catalogued as rs1276276631; called by muse, mutect2
- ZNF223 | c.-30C>T | 5'UTR (SNP) | VAF 8/153 reads (5%) | called by muse, mutect2
